Somatic mutation profile of tumor specimen MMRF_2167_1_BM_CD138pos (aliquot MMRF_2167_1_BM_CD138pos_T1_KHS5U_L08844) from MMRF case MMRF_2167, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.3 years (25,665 days).
Specimen MMRF_2167_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4287b05-4cb5-462f-bc50-77a6a64bff16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2167_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2167_1_PB_Whole_C2_KHS5U_L08789; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6336cc2-9113-4bc4-a5ca-e79722129969

The open-access MAF lists 116 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 29, Intron 15, Silent 15, 5'UTR 7, 5'Flank 4, Nonsense Mutation 2, RNA 2, Frame Shift Ins 1, Splice Site 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/184 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCB9 | c.1789A>G p.T597A (on ENST00000280560 / NM_019625.4; = p.T554A on NM_019624.3) | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV54891718; called by muse, mutect2, varscan2
- ANKS1B | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 48/97 reads (49%) | catalogued as COSV61335084, COSV61338267; called by muse, mutect2, varscan2
- ARMC5 | c.2339G>A p.G780D | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99192772; called by muse, mutect2, varscan2
- BPIFA2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs372285288; called by muse, mutect2, varscan2
- GRIP2 | c.389C>A p.A130E (on ENST00000619221; = p.A33E on NM_001080423.4) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs753399269; called by muse, mutect2
- IGHV2-70 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs374002647; called by muse, varscan2
- IGHV2-70 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs544365977; called by muse, varscan2
- IGLV3-25 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as rs1224954062; called by muse, mutect2
- MAMSTR | c.664G>A p.G222S (on ENST00000318083 / NM_001130915.2; = p.G119S on NM_182574.2) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1462019087; called by muse, mutect2, varscan2
- PICALM | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as rs367940264; called by muse, mutect2, varscan2
- PRDM16 | c.2159C>G p.P720R | Missense Mutation (SNP) | VAF 142/159 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV54605166; called by muse, mutect2, varscan2
- SLC26A8 | c.1486T>C p.S496P | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs769977831; called by muse, mutect2, varscan2
- VMP1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1351145318; called by muse, mutect2, varscan2
- ZNF726 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as rs1337993881; called by muse, mutect2
- ACTB | c.47T>C p.M16T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CACNA1S | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CIITA | c.1925T>C p.V642A | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CILP2 | c.1921G>A p.G641S | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL6A3 | c.1801C>A p.L601M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DZIP1L | c.1017A>C p.R339S | Missense Mutation (SNP) | VAF 176/266 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- FAT3 | c.8272A>T p.I2758L | Missense Mutation (SNP) | VAF 87/294 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GBF1 | c.4610C>G p.T1537S (on ENST00000369983 / NM_001377137.1; = p.T1536S on NM_004193.3) | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.51); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GRK2 | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 95/167 reads (57%) | called by muse, mutect2, varscan2
- KALRN | c.4692C>A p.N1564K | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT5C | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- KRTAP24-1 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- LIMS1 | c.645+2T>G p.X215_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- MED23 | c.2388G>C p.M796I | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MYH11 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NTRK2 | c.1549T>A p.F517I (on ENST00000323115 / NM_001369534.1; = p.F533I on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2L3 | c.803C>A p.T268K | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PCLO | c.13739G>T p.G4580V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PSMF1 | c.-21-8T>G | Splice Region (SNP) | VAF 63/158 reads (40%) | called by muse, mutect2, varscan2
- PURA | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SEC24C | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, varscan2
- SLC26A3 | c.682T>G p.F228V | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SON | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SULT1E1 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCEA1 | c.796_803del p.C266Efs*12 | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | called by mutect2, pindel
- TENT5C | c.723_724dup p.G242Afs*26 | Frame Shift Ins (INS) | VAF 64/109 reads (59%) | called by mutect2, pindel, varscan2
- WFDC6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF610 | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CDH12 | c.1698C>T p.F566= | Silent (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- EXD2 | c.864C>T p.V288= (on ENST00000312994 / NM_001193362.1; = p.V163= on NM_018199.3) | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as rs775769920, COSV57280353; called by muse, mutect2, varscan2
- GALNT14 | c.1551C>T p.C517= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- GPRASP1 | c.1893C>T p.S631= | Silent (SNP) | VAF 24/26 reads (92%) | called by muse, mutect2, varscan2
- H2BC3 | c.15T>G p.S5= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs746964834; called by muse, mutect2, varscan2
- ITGB4 | c.2193A>G p.L731= | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- MYT1L | c.333C>T p.S111= | Silent (SNP) | VAF 87/172 reads (51%) | catalogued as rs376911275, COSV67728613; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB15 | c.2214C>T p.D738= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs782560047, COSV50861759; called by muse, mutect2, varscan2
- PEX2 | c.258A>G p.K86= | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- PLCB2 | c.2796G>A p.A932= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- PLTP | c.687C>T p.N229= | Silent (SNP) | VAF 44/50 reads (88%) | called by muse, mutect2, varscan2
- SLC22A25 | c.387C>A p.S129= | Silent (SNP) | VAF 74/117 reads (63%) | called by muse, mutect2, varscan2
- SLC44A2 | c.1101C>G p.T367= | Silent (SNP) | VAF 72/279 reads (26%) | called by muse, mutect2, varscan2
- ZFHX3 | c.1344C>T p.D448= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs781434863, COSV99196304; called by muse, mutect2, varscan2
- ZNF83 | c.183T>C p.S61= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV56528348; called by muse, mutect2, varscan2
- AATK | c.190-1507C>A | Intron (SNP) | VAF 35/120 reads (29%) | catalogued as rs1046893685; called by muse, mutect2, varscan2
- AC018563.1 | n.632C>T | RNA (SNP) | VAF 53/280 reads (19%) | called by muse, mutect2, varscan2
- ADAM10 | c.*2103G>A | 3'UTR (SNP) | VAF 25/136 reads (18%) | called by muse, mutect2, varscan2
- AMOTL2 | c.*1203C>T | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- ANP32A | c.54+2422A>G | Intron (SNP) | VAF 57/132 reads (43%) | catalogued as rs1303993913; called by muse, mutect2, varscan2
- ARL4C | c.*877A>C | 3'UTR (SNP) | VAF 59/128 reads (46%) | called by muse, mutect2, varscan2
- ATL3 | chr11:63671666 del TTTGGGAATTGTAGTCCCGCGCTCACTGGGTCCCGGCCAGCGG | 5'Flank (DEL) | VAF 40/190 reads (21%) | called by mutect2, pindel
- BCL7A | chr12:122021574 G>A | 5'Flank (SNP) | VAF 42/85 reads (49%) | catalogued as rs1414138562, COSV104379335; called by muse, varscan2
- C5orf58 | chr5:170232964 G>A | 5'Flank (SNP) | VAF 50/162 reads (31%) | called by muse, mutect2, varscan2
- CAMK2B | c.-167C>T | 5'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- CAP2 | c.*1041T>A | 3'UTR (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- CD180 | c.-97T>A | 5'UTR (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- CDH20 | c.*21C>T | 3'UTR (SNP) | VAF 24/72 reads (33%) | catalogued as rs544737485; called by muse, mutect2, varscan2
- DCAF12 | c.*928G>A | 3'UTR (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- DLGAP2 | c.*904T>C | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- EGR1 | c.-100A>G | 5'UTR (SNP) | VAF 25/41 reads (61%) | called by muse, mutect2, varscan2
- EPHA5 | c.*1213G>T | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- GNG12 | c.*3572G>A | 3'UTR (SNP) | VAF 5/75 reads (7%) | catalogued as rs1339086458; called by muse, mutect2
- GNPAT | c.*212A>G | 3'UTR (SNP) | VAF 60/141 reads (43%) | called by muse, mutect2, varscan2
- GTF2H4 | chr6:30914129 G>A | 3'Flank (SNP) | VAF 25/92 reads (27%) | catalogued as rs946750254; called by muse, mutect2, varscan2
- HMGA2 | c.249+19576A>G | Intron (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- IGDCC3 | c.*1541G>A | 3'UTR (SNP) | VAF 17/81 reads (21%) | catalogued as rs920525349; called by muse, mutect2, varscan2
- ITPR3 | c.-100G>A | 5'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- KMT5B | c.1174+1235G>A | Intron (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- LHX2 | chr9:124008028 C>T | 5'Flank (SNP) | VAF 79/301 reads (26%) | catalogued as rs770726043; called by muse, mutect2, varscan2
- MPIG6B | c.*1221C>T | 3'UTR (SNP) | VAF 75/237 reads (32%) | called by muse, mutect2, varscan2
- NCKAP5 | c.341+6352G>T | Intron (SNP) | VAF 75/155 reads (48%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*782G>A | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- NFIB | c.*5523del | 3'UTR (DEL) | VAF 13/37 reads (35%) | catalogued as rs960514516, COSV66639342; called by mutect2, varscan2
- NRP2 | c.*3039del | 3'UTR (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- NSUN6 | c.*169G>T | 3'UTR (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- P2RY8 | c.*75A>G | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- P3H2 | c.956-74G>C | Intron (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2
- PACRG | c.613+101560G>C | Intron (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- PCDH10 | c.-72T>A | 5'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- PRKAB2 | c.*2599A>C | 3'UTR (SNP) | VAF 5/133 reads (4%) | catalogued as rs1047642091; called by muse, mutect2
- PRSS2 | c.200+75A>G | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, varscan2
- PRUNE2 | c.756+35269A>T | Intron (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- PTDSS1 | c.*2110C>G | 3'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.*445T>A | 3'UTR (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- RAB3B | c.*5998G>T | 3'UTR (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- RCC1 | c.-228-241C>T | Intron (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- SAYSD1 | c.208-3586C>T | Intron (SNP) | VAF 121/428 reads (28%) | called by muse, varscan2
- SEZ6L | c.*482G>A | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- SHISA5 | c.315-3221G>C | Intron (SNP) | VAF 91/269 reads (34%) | called by muse, mutect2, varscan2
- SLC13A1 | c.*1049A>C | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- SLC7A5 | c.*2034C>A | 3'UTR (SNP) | VAF 58/151 reads (38%) | called by muse, mutect2, varscan2
- STC1 | c.-230A>G | 5'UTR (SNP) | VAF 5/77 reads (6%) | catalogued as rs905711664, COSV99282545; called by muse, mutect2
- TAMALIN | c.549-23A>G | Intron (SNP) | VAF 62/120 reads (52%) | called by muse, varscan2
- TLE4 | c.-465A>C | 5'UTR (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- TRIM9 | c.1604-697G>A | Intron (SNP) | VAF 66/147 reads (45%) | catalogued as rs548156220; called by muse, mutect2, varscan2
- UBE2K | c.*1767T>C | 3'UTR (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- VMA21 | c.*814A>G | 3'UTR (SNP) | VAF 37/38 reads (97%) | called by muse, mutect2, varscan2
- WDR36 | c.359-63_359-33del | Intron (DEL) | VAF 33/136 reads (24%) | called by mutect2, pindel
- WTAP | c.*485G>A | 3'UTR (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- ZNF286A | c.*2755A>T | 3'UTR (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- ZNF891 | c.*12909dup | 3'UTR (INS) | VAF 30/72 reads (42%) | called by mutect2, pindel, varscan2
- ZNF971P | n.839C>A | RNA (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
